Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6884, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6884-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 5

Date:

Examination: Histopathological examination

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total organ resection – rectum and sigmoid colon**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**

Clinical diagnosis: **Cancer of the rectosigmoid junction**

Examination performed on:

Macroscopic description:

A 21.3 cm length of the large intestine with mesorectum tissue of 2 cm in thickness. Ulcerous tumour sized 3.3 x 3.4 x 0.7 cm found in the mucosa, sized 2.6 x 1.8 x 0.6 cm. The lesion surrounds 100% of the intestine circumference narrowing its lumen, is located 12.7 cm from the proximal incision line and 3.6 cm from the distal incision line.

Microscopic description:

Adenocarcinoma tubulare (G2).

Infiltratio carcinomatosa telae adiposae mesorecti.

Incision lines clear free of neoplastic lesions.

Metastases carcinomatosae in lymphonodis (No III / VIII).

Histopathological diagnosis:

Adenocarcinoma tubulare recti. Tubular adenocarcinoma of the rectum.

Metastases carcinomatosae in lymphonodis regionalis. Cancer metastases in regional lymph nodes. (No III / VIII). (G2, Dukes C, Astler-Coller C2, pT3, pN1, R0).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file d4cfdfa6-5829-4989-92c8-92cece844cac (TCGA-EI-6884.8C203621-A2D5-462C-A0B1-07F5A9F317CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).